Gene-level copy-number profile of tumor specimen TCGA-LP-A4AV-01A from TCGA case TCGA-LP-A4AV, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G2.
Specimen TCGA-LP-A4AV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.7c924fd6-3478-46b2-83a1-f7bd2c768e01.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LP-A4AV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6506690a-49cd-48ec-98bf-3cbeaab0263c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,277; copy number 3: 4,186; copy number 4: 41,104; copy number 5: 1,209; copy number 6: 6,080; copy number 7: 3,430; copy number 9: 1,529.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LP-A4AV-01A-11D-A242-01): tumor purity 0.7, ploidy 2.14, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,529 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:247,416,156–248,919,946, 86 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr3:119,821,321–198,222,513, 1,443 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
